Somatic mutation profile of tumor specimen TCGA-N8-A4PL-01A (aliquot TCGA-N8-A4PL-01A-11D-A28R-08) from TCGA case TCGA-N8-A4PL, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Age at diagnosis: 82.3 years (30,069 days).
Specimen TCGA-N8-A4PL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc3609a0-2859-4dd1-a398-280342105f17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N8-A4PL-10A (Blood Derived Normal), aliquot TCGA-N8-A4PL-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2433f7d5-9af4-44ff-b384-f425ad9dd761

The open-access MAF lists 53 somatic variants for this specimen: 37 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 15, In Frame Del 1, Splice Region 1, 3'Flank 1, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 8/9 reads (89%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 27/69 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 24/43 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as rs747514149, COSV55113269; called by muse, mutect2, varscan2
- ABCA9 | c.3134T>C p.I1045T | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as rs144122311; called by muse, mutect2, varscan2
- ADAMTSL1 | c.640C>A p.H214N | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.115); catalogued as rs762356888; called by muse, mutect2, varscan2
- AHNAK | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs138061218; called by muse, mutect2, varscan2
- ARAP3 | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.743); catalogued as rs189760075; called by muse, mutect2, varscan2
- ARHGAP30 | c.1460C>A p.A487E | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1039596140; called by muse, mutect2, varscan2
- B3GAT1 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as rs1437818366; called by muse, mutect2, varscan2
- CYP4F3 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as rs374257337; called by muse, mutect2, varscan2
- EXOC7 | c.2116G>A p.V706M (on ENST00000335146 / NM_001145297.4; = p.V624M on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT tolerated (0.12); PolyPhen benign (0.225); catalogued as rs778698782, COSV58035070; called by muse, mutect2, varscan2
- GEM | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370285889; called by muse, mutect2, varscan2
- LGR6 | c.452C>G p.S151C (on ENST00000367278 / NM_001017403.1; = p.S99C on NM_021636.3) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99707579; called by muse, mutect2, varscan2
- PCDH9 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV100122490; called by muse, mutect2, varscan2
- PCDHB2 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.192); catalogued as rs782217826, COSV99164208; called by muse, mutect2, varscan2
- PEG3 | c.3412C>T p.R1138W | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs750082564; called by muse, mutect2, varscan2
- SRSF9 | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as COSV99986750; called by muse, varscan2
- TTLL4 | c.2296C>T p.R766W | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1306377023, COSV51440225; called by muse, mutect2, varscan2
- ALDH2 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); called by muse, mutect2
- CAND2 | c.2303G>C p.R768P (on ENST00000456430 / NM_001162499.2; = p.R675P on NM_012298.3) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP4Z1 | c.65T>A p.M22K | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- DNLZ | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM160A2 | c.2280C>A p.N760K (on ENST00000449352 / NM_001098794.2; = p.N774K on NM_032127.4) | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- GAPDH | c.252A>C p.K84N | Missense Mutation (SNP) | VAF 160/338 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPLD1 | c.489T>C p.F163= | Splice Region (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- HUS1 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IVNS1ABP | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- KIF11 | c.642A>C p.L214F | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LYPLA2 | c.50_55del p.V17_S18del | In Frame Del (DEL) | VAF 20/88 reads (23%) | called by mutect2, pindel, varscan2
- NOP2 | c.2424G>C p.Q808H (on ENST00000322166 / NM_001258308.2; = p.Q804H on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN6 | c.505_510dup p.V169_M170dup | In Frame Ins (INS) | VAF 48/108 reads (44%) | called by mutect2, varscan2
- SDK2 | c.6021G>C p.K2007N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by mutect2, varscan2
- SLCO5A1 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TSG101 | c.885T>A p.D295E | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFHX3 | c.10365del p.F3456Sfs*29 | Frame Shift Del (DEL) | VAF 50/79 reads (63%) | called by mutect2, pindel, varscan2
- ALOX12 | c.270G>A p.A90= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV52352291; called by muse, mutect2, varscan2
- ARNTL | c.903C>T p.D301= (on ENST00000403290 / NM_001297719.2; = p.D300= on NM_001178.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 36/38 reads (95%) | called by muse, mutect2, varscan2
- DENND3 | c.1230C>T p.F410= | Silent (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2, varscan2
- DOK7 | c.327C>T p.G109= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs377367035; ClinVar: uncertain significance; called by muse, varscan2
- GM2A | c.558C>T p.I186= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs776606375, COSV64095210; called by muse, mutect2, varscan2
- JAKMIP1 | c.1500C>T p.R500= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs149678000; called by muse, mutect2, varscan2
- KCNIP4 | c.339G>A p.S113= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs771579238; called by muse, mutect2, varscan2
- MYH8 | c.3279G>A p.L1093= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV67961440; called by muse, mutect2, varscan2
- OR2W1 | c.684G>A p.T228= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs144276666, COSV65851448; called by muse, mutect2, varscan2
- OSBPL6 | c.1029C>A p.S343= | Silent (SNP) | VAF 79/168 reads (47%) | catalogued as COSV99506440; called by muse, mutect2, varscan2
- PIP5K1A | c.564C>T p.D188= (on ENST00000368888 / NM_001135638.2; = p.D175= on NM_003557.3) | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs587724514; called by muse, mutect2, varscan2
- PPL | c.717C>T p.Y239= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs140083031; called by muse, mutect2, varscan2
- SLC26A7 | c.679C>A p.R227= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs200934477, COSV52592539, COSV99404314; called by muse, mutect2, varscan2
- TINF2 | c.1023G>A p.K341= | Silent (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- USP48 | c.961T>C p.L321= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2
- MCMDC2 | chr8:66922490 A>C | 3'Flank (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
